Somatic mutation profile of tumor specimen C3L-06227-04 (aliquot CPT0456940008) from CPTAC case C3L-06227, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 62.6 years (22,880 days).
Specimen C3L-06227-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b62f2449-7e9c-4656-bb49-62b02a8e89fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06227-31 (Blood Derived Normal), aliquot CPT0457060003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cc34859-83c2-4df3-ac65-f50d6118d46b

The open-access MAF lists 236 somatic variants for this specimen: 157 protein-altering or splice-affecting, 69 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 69, Nonsense Mutation 14, 5'Flank 5, Intron 4, Splice Region 4, Frame Shift Del 3, Splice Site 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK4 | c.65A>T p.K22M | Missense Mutation (SNP) | VAF 95/374 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56984819, COSV56985325; called by muse, mutect2, varscan2
- ABCG1 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.074); catalogued as COSV59205832; called by muse, mutect2, varscan2
- AMBN | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as rs769376399; called by muse, mutect2, varscan2
- ARRDC2 | c.681C>A p.F227L | Missense Mutation (SNP) | VAF 148/501 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV99716565; called by muse, mutect2, varscan2
- ASH1L | c.5098C>T p.P1700S | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV64208204; called by muse, mutect2, varscan2
- ATP8A1 | c.3361T>A p.L1121M | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as rs1212537397; called by muse, mutect2
- C3orf85 | c.48C>T p.I16= | Splice Region (SNP) | VAF 85/300 reads (28%) | catalogued as rs187839586; called by muse, mutect2, varscan2
- CASP14 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 56/266 reads (21%) | catalogued as COSV99693051; called by muse, mutect2, varscan2
- CD300C | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV58169913; called by muse, mutect2, varscan2
- CDC20B | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs267600653; called by muse, mutect2, varscan2
- CDH19 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 104/387 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs149876065; called by muse, mutect2, varscan2
- CEP85L | c.934A>G p.R312G | Missense Mutation (SNP) | VAF 75/325 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs748580859; called by muse, mutect2, varscan2
- CFAP46 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs149173855; called by muse, mutect2, varscan2
- CFHR3 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs759117982; called by muse, mutect2, varscan2
- CGNL1 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV55570024; called by muse, mutect2, varscan2
- CNTN5 | c.1631C>A p.S544* | Nonsense Mutation (SNP) | VAF 5/92 reads (5%) | catalogued as rs1299614537; called by muse, mutect2
- CRACR2B | c.101C>G p.A34G | Missense Mutation (SNP) | VAF 147/437 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV58990325; called by muse, mutect2, varscan2
- DMBT1 | c.5503G>A p.D1835N (on ENST00000338354 / NM_001377530.1; = p.D1078N on NM_004406.3) | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.901); catalogued as rs750760735, COSV57536608; called by muse, mutect2, varscan2
- DMRTA1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.029); catalogued as COSV57924364; called by muse, mutect2, varscan2
- DPF1 | c.378C>T p.I126= | Splice Region (SNP) | VAF 63/258 reads (24%) | catalogued as rs1037554838, COSV62792486; called by muse, mutect2, varscan2
- DSCAM | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV68026863; called by muse, mutect2, varscan2
- DSG3 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs370472156, COSV57126751; called by muse, mutect2, varscan2
- FAT3 | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 71/202 reads (35%) | catalogued as COSV53087104, COSV53153984, COSV99961331; called by muse, mutect2, varscan2
- FAT4 | c.14861C>T p.S4954F | Missense Mutation (SNP) | VAF 110/368 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100628728, COSV58687122; called by muse, mutect2, varscan2
- FBF1 | c.1937G>A p.R646Q (on ENST00000586717; = p.R660Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs935636616; called by muse, mutect2
- FCRL5 | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV62511879, COSV62512606; called by muse, mutect2, varscan2
- FER1L5 | c.1193C>T p.S398L (on ENST00000623019; = p.S415L on NM_001293083.2) | Missense Mutation (SNP) | VAF 91/282 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1267013337, COSV70068705; called by muse, mutect2, varscan2
- FSIP2 | c.13486G>A p.D4496N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs1049486615; called by muse, mutect2, varscan2
- FSTL5 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 132/408 reads (32%) | catalogued as COSV60192829; called by muse, mutect2, varscan2
- FTMT | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as COSV58420332; called by muse, mutect2, varscan2
- GAS2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs888035146; called by muse, mutect2, varscan2
- GRIK2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs375405316; called by muse, mutect2
- HHLA2 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as rs752698352, COSV63320189; called by muse, mutect2, varscan2
- HYOU1 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782804402, COSV68216482; called by muse, mutect2, varscan2
- IPCEF1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1013851697, COSV54545217; called by muse, mutect2, varscan2
- JAKMIP1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 87/401 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV51541162; called by muse, mutect2, varscan2
- KCNB2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV73049978; called by muse, mutect2, varscan2
- KIAA1614 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 219/702 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV62550600, COSV62551693; called by muse, mutect2, varscan2
- LCE1F | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 263/604 reads (44%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs903800073; called by muse, mutect2, varscan2
- MINK1 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 82/245 reads (33%) | catalogued as COSV61792013; called by muse, mutect2, varscan2
- MYH7 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 160/545 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as COSV62522053; called by muse, mutect2, varscan2
- NCKAP1L | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as rs753722341; called by muse, mutect2, varscan2
- NPAS1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV101463948; called by muse, mutect2, varscan2
- OR2M3 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV71758873; called by muse, mutect2, varscan2
- OR5B17 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs764197115; called by muse, mutect2, varscan2
- PABPC3 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 106/429 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1259941948; called by muse, mutect2, varscan2
- RB1CC1 | c.2685G>T p.L895F | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV50266734; called by muse, mutect2, varscan2
- RBM25 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99998604; called by muse, mutect2, varscan2
- RYR2 | c.9667G>A p.E3223K | Missense Mutation (SNP) | VAF 120/498 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs556291797, COSV63684905, COSV63711474; called by muse, mutect2, varscan2
- SAFB2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 69/234 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs548530941; called by muse, mutect2, varscan2
- SELENOS | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 95/335 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV101237224; called by muse, mutect2, varscan2
- SLC38A10 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 143/510 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363250875; called by muse, mutect2, varscan2
- SLC39A12 | c.2011G>A p.G671R (on ENST00000377369 / NM_001145195.2; = p.G634R on NM_152725.3) | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173548312; called by muse, mutect2, varscan2
- SPRR2F | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 238/913 reads (26%) | PolyPhen possibly damaging (0.708); catalogued as COSV64205105; called by muse, mutect2, varscan2
- TAF11L12 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 119/359 reads (33%) | catalogued as rs550989787; called by muse, mutect2, varscan2
- TAF1L | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 191/540 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1284314192, COSV99644622; called by muse, mutect2, varscan2
- TBC1D1 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1444527229, COSV54713473; called by muse, mutect2, varscan2
- TBX15 | c.389G>A p.G130E (on ENST00000369429 / NM_001330677.2; = p.G24E on NM_152380.3) | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52872129; called by muse, mutect2, varscan2
- TENM3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV69299328; called by muse, mutect2, varscan2
- TEX13B | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 148/247 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57203518; called by muse, mutect2, varscan2
- TM4SF4 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as rs201039335; called by muse, mutect2, varscan2
- TMCO3 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 167/358 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1481979156, COSV64807068; called by muse, mutect2, varscan2
- TTN | c.49730G>A p.R16577Q (on ENST00000591111; = p.R9153Q on NM_003319.4) | Missense Mutation (SNP) | VAF 117/438 reads (27%) | PolyPhen possibly damaging (0.69); catalogued as rs143643360; called by muse, mutect2, varscan2
- WDFY4 | c.7469G>A p.G2490E | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347861913, COSV55438780; called by muse, mutect2, varscan2
- WDR81 | c.5515G>A p.G1839S (on ENST00000409644 / NM_001163809.2; = p.G788S on NM_152348.4) | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs1262075537; called by muse, mutect2, varscan2
- ZFHX2 | c.6536G>A p.R2179Q | Missense Mutation (SNP) | VAF 113/447 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs267603956; called by muse, mutect2, varscan2
- ZNF644 | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV61350584; called by muse, mutect2
- ZNF665 | c.325C>T p.R109* (on ENST00000600412; = p.R174* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/302 reads (7%) | catalogued as rs1042133945; called by muse, mutect2
- ZNF80 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 121/400 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs143027025; called by muse, mutect2, varscan2
- ABCA5 | c.440_464del p.P147Qfs*26 | Frame Shift Del (DEL) | VAF 66/203 reads (33%) | called by mutect2, pindel, varscan2
- ADAR | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 204/490 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.5); called by muse, varscan2
- ADGRG4 | c.6965C>T p.S2322F | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALG9 | c.1528C>G p.R510G (on ENST00000614444 / NM_001352418.1; = p.R517G on NM_024740.2) | Missense Mutation (SNP) | VAF 67/285 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP30 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMH4 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C2orf16 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2orf92 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- C9 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 136/430 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CACNA1C | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CACNA2D1 | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CACUL1 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMKV | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 176/534 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CCR2 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 91/350 reads (26%) | called by muse, mutect2, varscan2
- CDH20 | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CEP170B | c.305A>C p.Q102P (on ENST00000453495; = p.Q32P on NM_015005.3) | Missense Mutation (SNP) | VAF 96/381 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- CFAP57 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CIBAR2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL12A1 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 102/409 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CPD | c.3977A>G p.K1326R | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNPEP | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DOCK2 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 30/504 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHB2 | c.2319C>A p.D773E (on ENST00000400191 / NM_001309193.2; = p.D774E on NM_004442.7) | Missense Mutation (SNP) | VAF 119/328 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ESRRG | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- EXD2 | c.17T>C p.L6S | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM184A | c.271dup p.I91Nfs*5 | Frame Shift Ins (INS) | VAF 73/254 reads (29%) | called by mutect2, pindel, varscan2
- FBN2 | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBN2 | c.3910G>A p.G1304R | Missense Mutation (SNP) | VAF 83/327 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL4 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 128/338 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- FGA | c.1827T>G p.S609R | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- FYB1 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 150/534 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HERC1 | c.2009T>C p.V670A | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHE | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 143/448 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, varscan2
- IQGAP3 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KCNJ10 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 102/519 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- KCNK9 | c.767G>C p.R256P | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- KIF6 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LRP1B | c.185C>A p.S62* | Nonsense Mutation (SNP) | VAF 106/342 reads (31%) | called by muse, mutect2, varscan2
- LYN | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 109/478 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MAOA | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 107/156 reads (69%) | called by muse, mutect2, varscan2
- MAP3K4 | c.4769G>A p.W1590* | Nonsense Mutation (SNP) | VAF 103/356 reads (29%) | called by muse, mutect2, varscan2
- MEPCE | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 299/811 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC16 | c.22969T>A p.F7657I | Missense Mutation (SNP) | VAF 130/407 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- NEB | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- NEO1 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- NEXMIF | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 173/258 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NPAP1 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 31/425 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2
- NSD3 | c.314A>T p.N105I | Missense Mutation (SNP) | VAF 106/425 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- OASL | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 115/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OR52K1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR5AC1 | c.850T>A p.F284I | Missense Mutation (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- OR9A2 | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 87/602 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OSMR | c.2306C>G p.T769S | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PADI4 | c.527-1G>A p.X176_splice | Splice Site (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 226/705 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIWIL2 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 28/516 reads (5%) | called by muse, mutect2
- PKHD1L1 | c.10600-1G>A p.X3534_splice | Splice Site (SNP) | VAF 129/250 reads (52%) | called by muse, mutect2, varscan2
- PLCG2 | c.3197A>G p.K1066R | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PRAMEF8 | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 92/471 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PTEN | c.719_722del p.Y240Lfs*15 | Frame Shift Del (DEL) | VAF 60/183 reads (33%) | called by mutect2, pindel, varscan2
- RASA2 | c.1891T>C p.F631L | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RIMBP3 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 74/820 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SCN9A | c.3923G>A p.R1308K (on ENST00000303354; = p.R1297K on NM_002977.3) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- SETBP1 | c.4700C>T p.S1567L | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC35A5 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A4 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC7A13 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 206/479 reads (43%) | called by muse, mutect2, varscan2
- SMG9 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 143/460 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SOX10 | c.516_519del p.K172Nfs*113 | Frame Shift Del (DEL) | VAF 132/530 reads (25%) | called by mutect2, pindel, varscan2
- SPATA21 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- SULF2 | c.1194G>A p.R398= | Splice Region (SNP) | VAF 87/295 reads (29%) | called by muse, mutect2, varscan2
- TENM4 | c.6334G>A p.D2112N | Missense Mutation (SNP) | VAF 131/477 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM266 | c.905G>A p.W302* | Nonsense Mutation (SNP) | VAF 142/496 reads (29%) | called by muse, mutect2, varscan2
- TONSL | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 255/578 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAV19 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 100/355 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRAV8-7 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TTN | c.34213G>A p.V11405I (on ENST00000591111; = p.V10478I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/107 reads (29%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA1 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 118/217 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- USP34 | c.9181A>T p.S3061C | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP36 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- WEE2 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 27/634 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- WNT7B | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- XPNPEP2 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 112/195 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZAN | c.528G>A p.L176= | Splice Region (SNP) | VAF 184/443 reads (42%) | called by muse, mutect2, varscan2
- ZNF385B | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 98/380 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF729 | c.1325A>C p.N442T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ABCA13 | c.11667G>A p.T3889= | Silent (SNP) | VAF 156/459 reads (34%) | catalogued as rs367685852; called by muse, mutect2, varscan2
- ABCB1 | c.2313C>T p.F771= | Silent (SNP) | VAF 110/287 reads (38%) | catalogued as COSV55947168; called by muse, mutect2, varscan2
- ACVR1B | c.54C>G p.L18= | Silent (SNP) | VAF 87/279 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.1101C>T p.S367= | Silent (SNP) | VAF 79/257 reads (31%) | called by muse, mutect2, varscan2
- ADCY10 | c.2649G>A p.L883= | Silent (SNP) | VAF 161/405 reads (40%) | called by muse, mutect2, varscan2
- AFF3 | c.3354C>T p.S1118= | Silent (SNP) | VAF 109/334 reads (33%) | called by muse, mutect2, varscan2
- ALX1 | c.39T>G p.P13= | Silent (SNP) | VAF 46/235 reads (20%) | called by muse, mutect2, varscan2
- ANKH | c.888C>T p.I296= | Silent (SNP) | VAF 81/303 reads (27%) | catalogued as COSV52486774; called by muse, mutect2, varscan2
- ARHGEF5 | c.978G>A p.R326= | Silent (SNP) | VAF 288/480 reads (60%) | called by muse, varscan2
- BHMT2 | c.849G>A p.G283= | Silent (SNP) | VAF 134/438 reads (31%) | catalogued as rs1046503674; called by muse, mutect2, varscan2
- BOD1L2 | c.78C>T p.I26= | Silent (SNP) | VAF 157/437 reads (36%) | called by muse, mutect2, varscan2
- C20orf96 | c.969C>T p.L323= (on ENST00000360321 / NM_153269.3; = p.L322= on NM_080571.1) | Silent (SNP) | VAF 99/384 reads (26%) | called by muse, mutect2, varscan2
- C3 | c.4533C>T p.C1511= | Silent (SNP) | VAF 93/315 reads (30%) | catalogued as COSV55581801; called by muse, mutect2, varscan2
- CDHR1 | c.1269G>A p.V423= | Silent (SNP) | VAF 110/299 reads (37%) | catalogued as rs967559308; called by muse, mutect2, varscan2
- CEP63 | c.1254C>T p.S418= | Silent (SNP) | VAF 129/356 reads (36%) | called by muse, mutect2, varscan2
- CFAP97D1 | c.207G>A p.K69= | Silent (SNP) | VAF 92/290 reads (32%) | called by mutect2, varscan2
- CHRNA9 | c.1023C>T p.I341= | Silent (SNP) | VAF 121/427 reads (28%) | called by muse, mutect2, varscan2
- COL4A3 | c.456G>A p.L152= | Silent (SNP) | VAF 102/363 reads (28%) | called by muse, mutect2, varscan2
- CYP11A1 | c.1321C>T p.L441= | Silent (SNP) | VAF 95/477 reads (20%) | called by muse, mutect2, varscan2
- DDX41 | c.348C>T p.I116= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as rs764626688; called by muse, mutect2, varscan2
- DNAH3 | c.7023G>A p.E2341= | Silent (SNP) | VAF 76/257 reads (30%) | called by muse, mutect2, varscan2
- DNAH5 | c.1305G>A p.A435= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs766746657, COSV54222215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1050C>T p.S350= | Silent (SNP) | VAF 129/393 reads (33%) | catalogued as rs778927326; called by muse, mutect2, varscan2
- DYSF | c.4893C>T p.F1631= | Silent (SNP) | VAF 59/193 reads (31%) | catalogued as rs151276652; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FCER2 | c.684G>A p.L228= | Silent (SNP) | VAF 95/314 reads (30%) | catalogued as rs866995831, COSV60917813; called by muse, mutect2, varscan2
- FOLH1 | c.594G>A p.G198= | Silent (SNP) | VAF 90/276 reads (33%) | catalogued as COSV57045962; called by muse, mutect2, varscan2
- FRAS1 | c.2373G>A p.R791= | Silent (SNP) | VAF 86/307 reads (28%) | called by muse, mutect2, varscan2
- GPAT4 | c.1008G>A p.K336= | Silent (SNP) | VAF 137/368 reads (37%) | catalogued as COSV67840547; called by muse, mutect2, varscan2
- GRIK2 | c.216C>T p.P72= | Silent (SNP) | VAF 69/250 reads (28%) | called by muse, mutect2, varscan2
- HTR1A | c.390C>T p.I130= | Silent (SNP) | VAF 114/398 reads (29%) | catalogued as COSV60502710; called by muse, mutect2, varscan2
- KCNT1 | c.3237A>G p.L1079= (on ENST00000488444; = p.L1105= on NM_020822.3) | Silent (SNP) | VAF 95/476 reads (20%) | called by muse, mutect2, varscan2
- KLHL6 | c.729C>T p.V243= | Silent (SNP) | VAF 106/389 reads (27%) | catalogued as rs559842876, COSV100384484; called by muse, mutect2, varscan2
- LGR6 | c.1383C>T p.S461= (on ENST00000367278 / NM_001017403.1; = p.S409= on NM_021636.3) | Silent (SNP) | VAF 80/333 reads (24%) | catalogued as rs1234713792, COSV99705971; called by muse, mutect2, varscan2
- MBL2 | c.21C>T p.L7= | Silent (SNP) | VAF 9/219 reads (4%) | called by muse, mutect2
- MIDEAS | c.3114C>T p.F1038= | Silent (SNP) | VAF 63/227 reads (28%) | catalogued as rs1426339439; called by muse, mutect2, varscan2
- MINK1 | c.1560C>T p.A520= | Silent (SNP) | VAF 81/251 reads (32%) | called by muse, mutect2, varscan2
- NEO1 | c.1305G>A p.T435= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as rs201573366; called by muse, mutect2, varscan2
- NLRX1 | c.1803C>T p.I601= | Silent (SNP) | VAF 117/408 reads (29%) | called by muse, mutect2, varscan2
- NPAS4 | c.231C>T p.I77= | Silent (SNP) | VAF 132/382 reads (35%) | catalogued as rs144382366, COSV60648737; called by muse, mutect2, varscan2
- OR10AG1 | c.780G>A p.R260= | Silent (SNP) | VAF 73/214 reads (34%) | catalogued as COSV100400152, COSV56634119, COSV56634644; called by muse, mutect2, varscan2
- OR2L8 | c.96C>T p.F32= | Silent (SNP) | VAF 162/350 reads (46%) | catalogued as COSV61725736; called by muse, mutect2, varscan2
- OR4C15 | c.384T>C p.S128= (on ENST00000314644; = p.S74= on NM_001001920.2) | Silent (SNP) | VAF 137/418 reads (33%) | called by muse, mutect2, varscan2
- OR5AC1 | c.849C>T p.S283= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- OR5B12 | c.102C>T p.L34= | Silent (SNP) | VAF 104/359 reads (29%) | catalogued as COSV56905414; called by muse, mutect2, varscan2
- PCDHB5 | c.825G>A p.G275= | Silent (SNP) | VAF 89/334 reads (27%) | catalogued as rs782556582; called by muse, mutect2, varscan2
- PDHX | c.837C>T p.P279= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as rs371579798; called by muse, mutect2, varscan2
- PLCL2 | c.514C>T p.L172= (on ENST00000615277 / NM_001144382.2; = p.L46= on NM_015184.5) | Silent (SNP) | VAF 96/299 reads (32%) | catalogued as rs540695724; called by muse, mutect2, varscan2
- POGLUT1 | c.627C>T p.F209= | Silent (SNP) | VAF 65/218 reads (30%) | called by muse, mutect2, varscan2
- PRDM10 | c.2520C>T p.S840= | Silent (SNP) | VAF 109/337 reads (32%) | catalogued as rs147787310; called by muse, mutect2
- RAD51AP2 | c.3417G>A p.R1139= | Silent (SNP) | VAF 60/206 reads (29%) | catalogued as COSV67587298; called by muse, mutect2, varscan2
- SBNO2 | c.417C>T p.N139= | Silent (SNP) | VAF 96/392 reads (24%) | catalogued as rs377154278; called by muse, mutect2
- SDR9C7 | c.636G>A p.K212= | Silent (SNP) | VAF 114/433 reads (26%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.216C>T p.I72= | Silent (SNP) | VAF 82/269 reads (30%) | called by muse, mutect2, varscan2
- SLC17A6 | c.924A>T p.T308= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SLC4A5 | c.2842C>T p.L948= | Silent (SNP) | VAF 106/327 reads (32%) | called by muse, mutect2, varscan2
- SNX20 | c.294C>T p.I98= | Silent (SNP) | VAF 42/191 reads (22%) | catalogued as COSV56056430; called by muse, mutect2, varscan2
- SORCS2 | c.759G>A p.L253= | Silent (SNP) | VAF 118/365 reads (32%) | called by muse, mutect2, varscan2
- SOX18 | c.879C>T p.Y293= | Silent (SNP) | VAF 117/412 reads (28%) | catalogued as rs1216782396; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2430C>T p.S810= | Silent (SNP) | VAF 66/229 reads (29%) | called by muse, mutect2, varscan2
- TEKT4 | c.216G>A p.L72= | Silent (SNP) | VAF 134/462 reads (29%) | called by muse, mutect2, varscan2
- TTLL10 | c.1737G>C p.S579= | Silent (SNP) | VAF 149/389 reads (38%) | called by muse, mutect2
- TTN | c.15459G>A p.K5153= (on ENST00000591111; = p.K4226= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/442 reads (28%) | catalogued as COSV60064143; called by muse, mutect2, varscan2
- WDFY4 | c.1929C>T p.V643= | Silent (SNP) | VAF 29/318 reads (9%) | called by muse, mutect2
- WDR87 | c.3654G>A p.K1218= | Silent (SNP) | VAF 123/412 reads (30%) | called by muse, mutect2, varscan2
- XDH | c.3690C>T p.I1230= | Silent (SNP) | VAF 169/524 reads (32%) | catalogued as rs747474813, COSV65149317; called by muse, mutect2, varscan2
- Z83844.2 | c.741C>T p.F247= | Silent (SNP) | VAF 102/329 reads (31%) | catalogued as rs769545953; called by muse, mutect2, varscan2
- ZNF260 | c.825C>T p.P275= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as rs528202813; called by muse, mutect2, varscan2
- ZNF703 | c.724C>T p.L242= | Silent (SNP) | VAF 128/579 reads (22%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.642C>T p.F214= | Silent (SNP) | VAF 35/513 reads (7%) | catalogued as rs868589843; called by muse, mutect2
- AL353804.4 | chrX:73822170 C>T | 5'Flank (SNP) | VAF 96/165 reads (58%) | called by muse, mutect2, varscan2
- CLEC10A | c.675+46G>A | Intron (SNP) | VAF 110/464 reads (24%) | catalogued as rs149367958, COSV54701893; called by muse, mutect2, varscan2
- DNAJC16 | c.*508C>T | 3'UTR (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- EPB41 | c.2184+5328C>T | Intron (SNP) | VAF 132/357 reads (37%) | called by muse, mutect2, varscan2
- GLCCI1 | chr7:7967713 T>C | 5'Flank (SNP) | VAF 150/404 reads (37%) | called by muse, mutect2, varscan2
- LTN1 | chr21:28992924 C>T | 5'Flank (SNP) | VAF 20/234 reads (9%) | catalogued as rs1361978205, COSV57478291; called by muse, mutect2
- PAXIP1 | chr7:155004115 C>G | 5'Flank (SNP) | VAF 107/705 reads (15%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2837C>T | Intron (SNP) | VAF 137/498 reads (28%) | catalogued as rs758878969; called by muse, mutect2, varscan2
- RHOBTB2 | chr8:22994594 G>A | 5'Flank (SNP) | VAF 97/384 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10360+2086G>A | Intron (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
